Surgical pathology report (de-identified scan), TCGA case TCGA-60-2720, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2720-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R RIGHT DISTAL PARATRACHEAL
B. 4L LEFT DISTAL PARATRACHEAL
C. LEVEL 7 SUBCARINAL
D. 2R RIGHT PROXIMAL PARATRACHEAL
E. RIGHT MIDDLE AND LOWER LOBE BI LOBECTOMY
F. LEVEL 7 LYMPH NODE PACKET
G. LEVEL 11R RIGHT UPPER LOBE
H. MEDIAL MARGIN
I. LATERAL MARGIN
J. 9R LYMPH NODE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Right lower lobe lung mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

TPA, TPD: Lymph nodes, 4R, 4L, level 7, 2R, excision: No malignancy identified

FSA-FSD: Lymph nodes, 4R, 4L, level 7, 2R, excision: No malignancy identified

FSE. Right middle lobe: Bronchial margin is negative for carcinoma but carcinoma is close to the bronchial margin, less than 3 mm from the bronchial margin and protrudes into the bronchial lumen.

GROSS DESCRIPTION:

A. 4R RIGHT DISTAL PARATRACHEAL

[page 2 of 4]
[REDACTED]

Received fresh and labeled with the patient name [REDACTED] designated "A - 4R right distal paratracheal" are 3 pieces of soft tan tissue ranging from 0.3 x 0.1 x 0.1 cm to 0.5 x 0.5 x 0.2 cm. The entire specimen is submitted for frozen section in cassette FSA.

B. 4L LEFT DISTAL PARATRACHEAL

Received fresh and labeled with the patient name [REDACTED] designated "B - 4L left distal paratracheal" are 3 fragments of pink-tan soft tissue ranging from 0.4 x 0.3 x 0.1 cm to 1.0 x 0.4 x 0.4 cm. The entire specimen is submitted for frozen section in cassette FSB.

C. LEVEL 7 SUBCARINAL

Received fresh and labeled with the patient name [REDACTED] designated "C - level 7 subcarinal" are 5 fragments of pink-tan soft tissue ranging from 0.3 x 0.2 x 0.1 cm to 0.4 x 0.3 x 0.1 cm. The entire specimen is submitted for frozen section in cassette FSC.

D. 2R RIGHT PROXIMAL PARATRACHEAL

Received fresh and labeled with the patient name [REDACTED] designated "D - 2R right proximal paratracheal" are 3 fragments of pink-tan soft tissue ranging from 0.5 x 0.3 x 0.1 cm to 0.6 x 0.4 x 0.1 cm. The entire specimen is submitted for frozen section in cassette FSD.

E. RIGHT MIDDLE AND LOWER LOBE BI LOBECTOMY

Received fresh and labeled right middle and lower lobe, bi-lobectomy is a 391 gm bi-lobectomy specimen. The middle lobe is 14 x 9 x 3 cm and the lower lobe is 15 x 9 x 5.5 cm. The pleural surface is smooth and the lower lobe is inked black. Shaved section is taken of the bronchial margin and submitted for frozen section. In the central area of the lower lobe is a 4.5 x 4.0 x 3.0 cm white-tan necrotic mass. It surrounds the central bronchi and infiltrates the main bronchial tree. The mass extends to the pleura. The remainder of the parenchyma has a red-tan and speckled anthracotic appearance. No additional masses or lesions are observed. A section of mass is submitted for tissue procurement. Representative sections are submitted as follows:

FSE1: frozen section of bronchial margin

E2-E9: sections of mass in association with bronchi, lymph nodes, pleura and parenchyma

E11: normal appearing parenchyma from middle lobe

E10 and E12: possible lymph nodes

F. LEVEL 7 LYMPH NODE PACKET

Received in formalin and labeled [REDACTED] "level 7 lymph node packet" is a piece of pink-brown soft tissue measuring 2.9 x 1.5 x 0.5 cm. Specimen is bisected and the cut surface has a variegated pink and black appearance. Specimen is submitted in toto in block F1-F2.

G. LEVEL 11R RIGHT UPPER LOBE

Received in formalin and labeled [REDACTED] "level 11R right upper lobe" are pieces of pink and black soft tissue in aggregate measuring 1.8 x 1.4 x 0.3 cm. Submitted in toto in block G1.

H. MEDIAL MARGIN

Received in formalin and labeled [REDACTED] "medial margin" is an unoriented piece of pink-tan soft tissue 1.0 x 0.5 x 0.3 cm. Submitted in block H1.

I. LATERAL MARGIN

[REDACTED]

[page 3 of 4]
[REDACTED]

Received in formalin and labeled [REDACTED] lateral margin" is a piece of pink-tan soft tissue, 0.3 x 0.3 x 0.2 cm. Submitted in block I1.

J. 9R LYMPH NODE

Received in formalin and labeled [REDACTED] "9R lymph node" is a piece of mottled black-tan soft tissue measuring 3.3 x 0.4 x 0.3 cm. Submitted in toto in block J1.

[REDACTED]

DIAGNOSIS:

- A. LYMPH NODE, 4R RIGHT DISTAL PARATRACHEAL, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- B. LYMPH NODE, 4L LEFT DISTAL PARATRACHEAL, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- C. LYMPH NODE, LEVEL 7 SUBCARINAL, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- D. LYMPH NODE, 2R RIGHT PROXIMAL PARATRACHEAL, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- E. LUNG, RIGHT MIDDLE AND LOWER LOBE, BI-LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, WITH EXTENSIVE NECROSIS.
- TUMOR MEASURES 4.5 x 4 x 3 CM AND IS PRESENT IN LOWER LOBE.
- TUMOR IS PRESENT IN BRONCHUS (SEE NOTE).
- PLEURAL MARGINS, NEGATIVE FOR CARCINOMA.
- NINE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/9).
- F. LYMPH NODE PACKET, LEVEL 7, DISSECTION:
- FIVE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/5).
- G. LYMPH NODE, LEVEL 11R RIGHT UPPER LOBE, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- H. LUNG, MEDIAL MARGIN, EXCISION:
- BRONCHIAL TISSUE WITH SQUAMOUS METAPLASIA AND DETACHED FRAGMENT OF DYSPLASTIC SQUAMOUS EPITHELIUM, NEGATIVE FOR CARCINOMA (SEE NOTE).
- I. LUNG, LATERAL MARGIN, EXCISION:
- BRONCHIAL TISSUE, NEGATIVE FOR CARCINOMA.
- J. LYMPH NODE, 9R, EXCISION:
[REDACTED]

[page 4 of 4]
[REDACTED]

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

NOTE: Tumor is present in the bronchial margin of the bi-lobectomy specimen on permanent sections. No tumor is seen in specimens H and I that were submitted as medial and lateral margins. The detached fragment of squamous epithelium seen in specimen H shows at least moderate dysplasia. Multiple levels of specimen H were examined and [REDACTED] reviewed selected slides of specimen H. A CD34 immunostain was performed with appropriate controls on slide E6 and shows no evidence of lymphovascular invasion.

SYNOPTIC REPORT - LUNG

Surgical Procedure: Lobectomy
Laterality: Right
Tumor Site: Lower lobe
Tumor Location: Central
Tumor Size: Greatest diameter: 4.5cm
Additional dimensions: 4cm x 3cm

WHO CLASSIFICATION
Squamous cell carcinoma
Conventional type 8070/3
Histologic Grade: G2: Moderately differentiated
Angiolymphatic Invasion: Absent
Bronchial Margins: Bronchial margins uninvolved
Comment: see specimens E, H, and I
Visceral Pleural Involvement: Absent
Satellite Tumor(s): Absent
Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 10
N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 10
Additional Pathologic Findings: Metaplasia
Type: squamous
Inflammation
Type: chronic
Pathological Staging (pTNM): pT 2 N 0 M X

Source: NCI Genomic Data Commons file 6197ed3f-50dc-4280-aa2b-36ee84323224 (TCGA-60-2720.02B1AE97-4962-46C8-9672-0597BDC85705.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).